Somatic mutation profile of tumor specimen TCGA-EE-A2GD-06A (aliquot TCGA-EE-A2GD-06A-11D-A196-08) from TCGA case TCGA-EE-A2GD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 83.6 years (30,547 days).
Specimen TCGA-EE-A2GD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15bb3299-e649-4e5c-88eb-0378adade8ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GD-10A (Blood Derived Normal), aliquot TCGA-EE-A2GD-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fd62f9b-ac25-4ce0-8cb7-edbced05adf1

The open-access MAF lists 651 somatic variants for this specimen: 429 protein-altering or splice-affecting, 198 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 393, Silent 198, Nonsense Mutation 23, RNA 8, Intron 8, Splice Region 7, 3'UTR 3, Frame Shift Del 3, 5'Flank 2, Splice Site 2, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs121908228, CM023611, COSV64211919; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HCN1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561081319, COSV57492050; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HOOK2 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV53403978; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- SLC22A5 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72552735, CM991138, COSV55374912; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1306C>T p.P436S (on ENST00000373993 / NM_138932.2; = p.P428S on NM_014576.4) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV50957440, COSV50964844; called by muse, mutect2, varscan2
- ABCC12 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375001140; called by mutect2, varscan2
- ABCG5 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 38/165 reads (23%) | catalogued as rs1252670145, COSV53213415; called by muse, mutect2, varscan2
- ABLIM1 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV53315467; called by muse, mutect2
- ACADM | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as COSV63721055; called by muse, mutect2, varscan2
- ACAN | c.7381G>A p.E2461K (on ENST00000560601 / NM_001369268.1; = p.E2385K on NM_001135.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs183636867; called by muse, mutect2, varscan2
- ACAP1 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV50134633; called by muse, mutect2, varscan2
- ACCSL | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV66582762; called by muse, mutect2, varscan2
- ACTL8 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV64862639; called by muse, mutect2
- ACTRT1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); catalogued as COSV64420010; called by muse, varscan2
- ADAM18 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55847852; called by muse, mutect2
- ADAMDEC1 | c.763-1G>A p.X255_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV56477488; called by muse, mutect2
- ADGRF5 | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | catalogued as COSV51939871; called by muse, mutect2, varscan2
- ADGRL4 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV66065708; called by muse, mutect2
- ADGRV1 | c.10552C>T p.H3518Y | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV67994870; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- AEBP1 | c.2200C>T p.L734F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV56261148; called by muse, mutect2, varscan2
- AGXT2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51484087, COSV51490592, COSV99183908; called by muse, mutect2, varscan2
- AHNAK2 | c.10231G>A p.V3411M | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs773412505, COSV60929670; called by muse, mutect2, varscan2
- AKR7A3 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs989461397, COSV64389719; called by muse, mutect2, varscan2
- AL592490.1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.095); catalogued as COSV69427538; called by muse, mutect2, varscan2
- ALLC | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV52997192; called by muse, mutect2, varscan2
- ANK3 | c.7103G>A p.G2368E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV55054382; called by muse, mutect2, varscan2
- ANK3 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs376032920; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs1313300543, COSV51857840; called by muse, mutect2, varscan2
- APBB1IP | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV66130834; called by muse, mutect2, varscan2
- APOA4 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs768855419, COSV63360536; called by muse, mutect2, varscan2
- APOB | c.9565C>T p.P3189S | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51946775; called by muse, mutect2, varscan2
- ARHGAP20 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52818950; called by muse, mutect2, varscan2
- ARHGAP5 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1259085620, COSV61539184; called by muse, mutect2, varscan2
- ARIH2 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as rs753506586, COSV62703728, COSV62706358; called by muse, mutect2, varscan2
- ARMC4 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV59465239; called by muse, mutect2, varscan2
- ARNT | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs868189404, COSV62231440, COSV62232250; called by muse, mutect2, varscan2
- ASB17 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.989); catalogued as rs200235376, COSV52412017; called by muse, mutect2, varscan2
- ASCC2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV57076528; called by muse, mutect2
- AURKC | c.374G>A p.R125K (on ENST00000302804 / NM_001015878.2; = p.R91K on NM_003160.3) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV57140037; called by muse, mutect2, varscan2
- BATF | c.254T>G p.V85G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54376806, COSV99708829; called by muse, mutect2, varscan2
- BCAS3 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV66781796; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BMPER | c.1176A>T p.K392N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV51830885; called by muse, mutect2, varscan2
- BUB1 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV57067197; called by muse, mutect2, varscan2
- C12orf40 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as rs1018177244, COSV61130151, COSV61137563; called by muse, mutect2
- CABIN1 | c.4478T>C p.F1493S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV54088775; called by muse, mutect2, varscan2
- CACNA1S | c.2157G>A p.K719= | Splice Region (SNP) | VAF 95/372 reads (26%) | catalogued as rs889659456, COSV62943450; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG2 | c.191G>A p.W64* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV55640770; called by muse, mutect2, varscan2
- CARD11 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs1419000024, COSV62753996; called by mutect2, varscan2
- CBL | c.2630C>T p.A877V | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV50662709; called by muse, mutect2, varscan2
- CCBE1 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67951512; called by muse, mutect2, varscan2
- CD163L1 | c.3998G>A p.S1333N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.46); catalogued as COSV58024219; called by muse, mutect2, varscan2
- CD209 | c.1085A>T p.N362I | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs1439844860, COSV52658617; called by muse, mutect2, varscan2
- CD33 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51804693; called by muse, mutect2, varscan2
- CD86 | c.975T>G p.S325R (on ENST00000330540 / NM_175862.5; = p.S319R on NM_006889.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV52610162; called by muse, varscan2
- CDR1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV65164792; called by muse, mutect2, varscan2
- CES3 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as COSV57595324; called by muse, mutect2, varscan2
- CFAP57 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV65265722; called by muse, mutect2, varscan2
- CFAP58 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV57213564; called by muse, mutect2, varscan2
- CHAT | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV60332631; called by muse, mutect2, varscan2
- CHRFAM7A | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100241654; called by mutect2, varscan2
- CIT | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1257747319, COSV55882625; called by muse, mutect2, varscan2
- CKM | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV53463629; called by muse, mutect2, varscan2
- CLCN5 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs140246004, COSV100260298; called by muse, mutect2, varscan2
- CLEC4E | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55227272; called by muse, mutect2, varscan2
- CLEC4E | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | catalogued as rs143517337; called by muse, mutect2, varscan2
- CLK1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs146248641; called by muse, mutect2, varscan2
- CLPS | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV52567360; called by muse, mutect2, varscan2
- CNTNAP2 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1186551916, COSV62252736; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2, varscan2
- COG1 | c.2697T>A p.H899Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55431918; called by muse, mutect2, varscan2
- COL1A2 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM156282, COSV51952421, COSV51965853; called by muse, mutect2, varscan2
- COL4A1 | c.4388G>A p.G1463E | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518459, COSV65431832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.3016G>A p.G1006R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65674426; called by muse, mutect2, varscan2
- COLEC12 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as COSV68372430; called by muse, mutect2
- CP | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765086883, COSV52833903; called by muse, mutect2, varscan2
- CRCT1 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | PolyPhen possibly damaging (0.821); catalogued as COSV100524236, COSV57501540; called by muse, mutect2, varscan2
- CRLF3 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV60837311; called by muse, mutect2, varscan2
- CST9 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV65402541; called by muse, mutect2, varscan2
- CUL1 | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV57392356; called by muse, varscan2
- CUL3 | c.1417A>T p.M473L | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52370323; called by muse, mutect2, varscan2
- CUL9 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV52734427; called by muse, mutect2, varscan2
- CXCR2 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59282044; called by muse, mutect2, varscan2
- CXCR2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as COSV59279898; called by muse, mutect2, varscan2
- CYP2C9 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53252671; called by muse, mutect2, varscan2
- CYP4A11 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.216); catalogued as COSV60225545; called by muse, mutect2, varscan2
- CYP4F22 | c.1031T>G p.I344S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV54111753; called by muse, mutect2, varscan2
- CYP4X1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV64151712; called by muse, mutect2, varscan2
- DCC | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV59133691; called by muse, mutect2, varscan2
- DCC | c.3881G>A p.G1294E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.665); catalogued as COSV71440440; called by muse, mutect2, varscan2
- DCTD | c.459G>A p.R153= | Splice Region (SNP) | VAF 12/68 reads (18%) | catalogued as rs769584873, COSV63867305; called by muse, mutect2
- DDR2 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63374265; called by muse, mutect2, varscan2
- DDX20 | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs370347142; called by muse, mutect2, varscan2
- DDX27 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193996648, COSV65610644; called by muse, mutect2, varscan2
- DEFA4 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV52405349; called by muse, mutect2, varscan2
- DENND1A | c.2390C>T p.T797I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV65356115; called by muse, mutect2, varscan2
- DENND1B | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.236); catalogued as rs1213502120, COSV54147668; called by muse, mutect2, varscan2
- DENND3 | c.3036G>A p.M1012I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV52806668; called by muse, mutect2, varscan2
- DNAH2 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66726837; called by muse, mutect2, varscan2
- DNAH2 | c.2052G>A p.R684= | Splice Region (SNP) | VAF 20/131 reads (15%) | catalogued as rs1302379013, COSV66726844; called by muse, varscan2
- DNAH8 | c.12184G>A p.E4062K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59478897; called by muse, mutect2, varscan2
- DNAH9 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as rs756842427, COSV52375746; called by muse, mutect2, varscan2
- DNAH9 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV52375755; called by muse, mutect2, varscan2
- DNAH9 | c.3024C>A p.S1008R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52375763; called by muse, mutect2, varscan2
- DNMT1 | c.3670C>T p.P1224S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61583613; called by muse, mutect2, varscan2
- DOCK10 | c.1598A>T p.N533I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV51427266; called by muse, mutect2, varscan2
- DOCK3 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV56547976, COSV99813725; called by muse, mutect2
- DUSP2 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391808269, COSV56620589; called by muse, mutect2
- DYRK2 | c.1714T>C p.S572P (on ENST00000344096 / NM_006482.3; = p.S499P on NM_003583.4) | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.68); catalogued as COSV59847422; called by muse, mutect2, varscan2
- EEPD1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV54203041; called by muse, mutect2, varscan2
- EFR3A | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV54462186; called by muse, mutect2, varscan2
- EGFLAM | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV59316455; called by muse, mutect2, varscan2
- ELAC2 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV100568289, COSV62034670; called by muse, mutect2, varscan2
- EML1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV51752028; called by muse, mutect2, varscan2
- ERC2 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV55661732; called by muse, mutect2, varscan2
- ERF | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.211); catalogued as COSV55897384; called by muse, mutect2, varscan2
- EVX2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57965050; called by muse, mutect2, varscan2
- EYA4 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.323); catalogued as COSV62060442; called by muse, mutect2, varscan2
- F11 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as CD052108, COSV53009555; called by muse, mutect2, varscan2
- F2RL1 | c.427T>A p.Y143N | Missense Mutation (SNP) | VAF 125/593 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56996836; called by muse, mutect2, varscan2
- FAM111A | c.637_638del p.V213Lfs*25 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs778387222; called by pindel, varscan2
- FAT4 | c.8044G>A p.E2682K | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58707903; called by muse, mutect2, varscan2
- FBXL13 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as rs750994268, COSV57542560; called by muse, mutect2, varscan2
- FCRL3 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1192017915, COSV100942990, COSV100943434; called by muse, mutect2, varscan2
- FGD3 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61595869; called by muse, mutect2, varscan2
- FGD6 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV59696982; called by muse, mutect2, varscan2
- FGF13 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.106); catalogued as COSV100264454; called by muse, varscan2
- FGF13 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as rs1322103153, COSV100264457; called by muse, mutect2, varscan2
- FNDC3A | c.1399C>T p.P467S (on ENST00000492622 / NM_001079673.2; = p.P411S on NM_014923.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV68135018; called by muse, mutect2, varscan2
- FOXA1 | c.242C>A p.A81E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.113); catalogued as COSV51649885; called by muse, mutect2, varscan2
- FOXK1 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs370402475; called by muse, mutect2
- FOXO4 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV58576403; called by muse, mutect2
- FRMD7 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV53748678; called by muse, mutect2, varscan2
- FSIP2 | c.19107T>A p.D6369E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.747); catalogued as COSV100555746; called by muse, mutect2, varscan2
- GAP43 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs767522147, COSV59348139; called by muse, mutect2, varscan2
- GART | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV101111369, COSV67819251; called by muse, mutect2, varscan2
- GFRA3 | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51231410; called by muse, mutect2, varscan2
- GK | c.1375G>A p.E459K (on ENST00000427190 / NM_001205019.2; = p.E453K on NM_000167.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1280851281, COSV66732573; called by muse, mutect2, varscan2
- GLI2 | c.1207G>T p.D403Y (on ENST00000361492 / NM_001374353.1; = p.D420Y on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58051053; called by muse, mutect2, varscan2
- GLRB | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs866482989, COSV52412584, COSV52414164; called by muse, mutect2, varscan2
- GLYATL2 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs1361662779, COSV54851495; called by muse, mutect2, varscan2
- GMPR2 | c.679G>T p.D227Y (on ENST00000355299 / NM_001351022.2; = p.D245Y on NM_016576.5) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57470607; called by muse, mutect2, varscan2
- GP2 | c.1062G>T p.R354S (on ENST00000381362 / NM_001007240.3; = p.R351S on NM_001502.4) | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV56892665, COSV56896566; called by muse, varscan2
- GPATCH1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV50125997; called by muse, mutect2, varscan2
- GPR158 | c.1850T>C p.V617A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV66282006; called by muse, mutect2, varscan2
- GPR174 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52134350; called by muse, mutect2, varscan2
- GPR20 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200892677, COSV66683841; called by mutect2, varscan2
- GPR39 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100257422, COSV61428766; called by muse, mutect2, varscan2
- GPR83 | c.410G>A p.W137* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV54717461; called by muse, mutect2, varscan2
- GRIK1 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58724926; called by muse, mutect2, varscan2
- GRIN2A | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV58050034; called by muse, mutect2, varscan2
- GRM2 | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs1294887398, COSV99623021; called by muse, mutect2, varscan2
- GRM2 | c.2405G>A p.G802D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV56583214; called by muse, mutect2, varscan2
- GUCY2F | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as COSV54308324; called by muse, mutect2, varscan2
- HDGFL2 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs201430193; called by muse, mutect2, varscan2
- HHIPL2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 119/527 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564422; called by muse, mutect2, varscan2
- HIBADH | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV55316846; called by muse, mutect2, varscan2
- HMCN1 | c.16657C>T p.R5553W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200641304, COSV54903854; called by muse, mutect2, varscan2
- HMGB3 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57486168; called by muse, mutect2, varscan2
- HNF4G | c.1193C>T p.S398L (on ENST00000354370 / NM_001330561.2; = p.S445L on NM_004133.5) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV62966500; called by muse, mutect2, varscan2
- HPX | c.216G>A p.G72= | Splice Region (SNP) | VAF 8/53 reads (15%) | catalogued as COSV56420568; called by muse, mutect2, varscan2
- HRH1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV101229080; called by muse, mutect2, varscan2
- HRH1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV67954988; called by muse, mutect2, varscan2
- ICAM5 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV55746751, COSV55749202; called by muse, mutect2
- IFNA8 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV66505015; called by muse, mutect2, varscan2
- IGF1 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV61034475; called by muse, mutect2, varscan2
- IGF2BP1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV51735732; called by muse, mutect2, varscan2
- IL17A | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780218416, COSV60684979, COSV60685375; called by muse, mutect2, varscan2
- IL17F | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60233895; called by muse, mutect2, varscan2
- IL1RL1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as COSV52115964; called by muse, mutect2, varscan2
- INAVA | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs867306525, COSV66257471; called by muse, mutect2, varscan2
- INO80D | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as rs371768681; called by muse, mutect2, varscan2
- INTS1 | c.2514C>T p.P838= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as rs371492368, COSV101248157; called by muse, mutect2, varscan2
- INTS1 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101248162; called by muse, mutect2, varscan2
- IQSEC2 | c.1834C>T p.R612C (on ENST00000642864 / NM_001111125.3; = p.R407C on NM_015075.2) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs868951322, COSV64727843; called by muse, mutect2, varscan2
- IRF2BP1 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV56195054; called by muse, mutect2, varscan2
- ISL1 | c.91A>T p.R31W | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57935644; called by muse, mutect2, varscan2
- ITGB8 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99751923; called by muse, mutect2, varscan2
- ITLN1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as rs760854751, COSV58276751; called by muse, mutect2, varscan2
- ITPKB | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs137905849; called by muse, mutect2, varscan2
- KCNB2 | c.2521G>A p.G841R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.404); catalogued as COSV73052897; called by muse, mutect2, varscan2
- KCND3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1183337083, COSV56180300; called by muse, mutect2, varscan2
- KCNK5 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV63989382; called by muse, varscan2
- KCNQ5 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59663959; called by muse, mutect2, varscan2
- KCNV1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV52088986; called by muse, mutect2, varscan2
- KCNV1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52088999; called by muse, mutect2, varscan2
- KHDC1 | c.330C>T p.F110= (on ENST00000370384 / NM_001251874.2; = p.F37= on NM_030568.5) | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as rs372154414; called by muse, mutect2
- KIAA1586 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV66057413; called by muse, mutect2, varscan2
- KLHL4 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV64147682; called by muse, mutect2, varscan2
- KLHL4 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as COSV100910021; called by muse, mutect2
- KRT16 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs1405646148, COSV56967380; called by muse, mutect2, varscan2
- KRT33A | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs768092751, COSV50375186; called by muse, mutect2, varscan2
- LAD1 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as rs143101113; called by muse, varscan2
- LAMA1 | c.6721G>A p.D2241N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV67544114; called by muse, mutect2, varscan2
- LARP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | PolyPhen benign (0.01); catalogued as rs1249362134, COSV60431158; called by muse, mutect2, varscan2
- LASP1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV58806006; called by muse, mutect2, varscan2
- LAX1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV65849171; called by muse, mutect2, varscan2
- LCE3D | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV64231194; called by muse, mutect2, varscan2
- LCK | c.876G>C p.M292I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV60740078, COSV60742627; called by muse, mutect2, varscan2
- LCT | c.2470G>A p.D824N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.43); catalogued as rs140434720; called by muse, mutect2, varscan2
- LINGO4 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746401391, COSV63216470; called by muse, varscan2
- LIPF | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV53285992; called by muse, mutect2, varscan2
- LMAN1L | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV59003665; called by muse, mutect2, varscan2
- LRP1B | c.13759C>T p.P4587S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.996); catalogued as COSV67266466; called by muse, mutect2, varscan2
- LRP1B | c.5683G>A p.E1895K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV67187289, COSV67257187; called by muse, mutect2, varscan2
- LRRC17 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV50867843; called by muse, mutect2, varscan2
- LRRC7 | c.4647G>A p.M1549I (on ENST00000651989 / NM_001370785.2; = p.M1469I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.166); catalogued as COSV50411055; called by muse, mutect2, varscan2
- LRRCC1 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV64485655; called by muse, mutect2, varscan2
- LSM14A | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as COSV70885683; called by muse, mutect2
- LUZP2 | c.955T>C p.C319R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.246); catalogued as COSV61208432; called by muse, mutect2, varscan2
- LY75 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs761552529, COSV55112683; called by muse, mutect2, varscan2
- MAGEA10 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV54885797; called by muse, mutect2, varscan2
- MAGEC3 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs758989764, COSV53577293; called by muse, mutect2, varscan2
- MAP3K19 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59642092; called by muse, mutect2, varscan2
- MCCC1 | c.2129C>T p.P710L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55611742; called by muse, mutect2, varscan2
- MCF2L2 | c.2333T>G p.M778R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV61061044; called by muse, mutect2, varscan2
- MCHR1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173396015, COSV50762850; called by muse, mutect2, varscan2
- MEFV | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs1185925415, COSV54827366; called by muse, mutect2, varscan2
- MEGF8 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs747511405, COSV52084678; called by muse, mutect2, varscan2
- METTL15 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57718536; called by muse, mutect2, varscan2
- MKI67 | c.6782C>T p.S2261L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV64076795; called by muse, mutect2, varscan2
- MORC2 | c.1535T>A p.L512Q (on ENST00000397641 / NM_001303256.3; = p.L450Q on NM_014941.3) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.959); catalogued as COSV53202496; called by muse, mutect2, varscan2
- MROH2B | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.359); catalogued as COSV68189291; called by muse, mutect2, varscan2
- MS4A4A | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100557947, COSV59703306; called by muse, mutect2, varscan2
- MS4A8 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55755798; called by muse, mutect2, varscan2
- MSANTD2 | c.1565C>T p.S522F (on ENST00000374979 / NM_001308027.2; = p.S470F on NM_024631.4) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV53451180; called by muse, mutect2, varscan2
- MUC16 | c.23912C>T p.S7971F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as COSV67491948; called by muse, mutect2, varscan2
- MYH2 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775146540, COSV55447883, COSV55450103; called by muse, mutect2, varscan2
- MYO3B | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV58716922; called by muse, mutect2, varscan2
- NBPF15 | c.42G>C p.E14D | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1427727025; called by muse, mutect2, varscan2
- NCAPG2 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs369184720; called by muse, mutect2, varscan2
- NDUFB5 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52021884; called by muse, mutect2
- NEK11 | c.1516A>T p.I506F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV67285809; called by muse, mutect2, varscan2
- NFIA | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV64536479, COSV64543864; called by muse, mutect2, varscan2
- NHS | c.3619C>T p.R1207C | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs138311675, COSV66279026; called by muse, mutect2, varscan2
- NID2 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV53502586; called by muse, mutect2, varscan2
- NLGN4X | c.2000C>T p.T667I | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV52035500; called by muse, mutect2, varscan2
- NOL8 | c.2734A>C p.K912Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV62638013; called by muse, mutect2, varscan2
- NOTCH3 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54642497, COSV54649251; called by muse, mutect2, varscan2
- NPAP1 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV61506653, COSV61510875; called by muse, mutect2, varscan2
- NR3C2 | c.2870C>A p.P957H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60996908, COSV60999635; called by muse, mutect2, varscan2
- NSD2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56396214; called by muse, mutect2, varscan2
- NSD3 | c.923A>T p.Y308F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57621951; called by muse, mutect2, varscan2
- NTRK3 | c.2269G>A p.G757R (on ENST00000360948 / NM_001012338.2; = p.G743R on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1361200565, COSV62311254; called by muse, mutect2, varscan2
- NUAK2 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs752515472, COSV65682598; called by muse, mutect2, varscan2
- NYNRIN | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.68); catalogued as rs756142193, COSV66841576; called by muse, mutect2, varscan2
- OGT | c.1917G>A p.M639I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV65482629; called by muse, mutect2, varscan2
- OLFM4 | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV54580376, COSV54581116; called by muse, mutect2, varscan2
- OR10AG1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267602985, COSV56632145; called by muse, mutect2, varscan2
- OR10P1 | c.644T>A p.I215N | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100548195; called by muse, mutect2, varscan2
- OR11G2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV62133038, COSV62133059; called by muse, mutect2, varscan2
- OR2M7 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs866709680, COSV58740651; called by muse, mutect2, varscan2
- OR2T2 | c.28T>A p.S10T | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV61619007; called by muse, mutect2, varscan2
- OR2W1 | c.409A>C p.N137H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.868); catalogued as COSV65851899; called by muse, varscan2
- OR2W1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV65851895, COSV65851905; called by muse, varscan2
- OR4A16 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs764086893, COSV59042703; called by muse, mutect2, varscan2
- OR4C3 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs758744609, COSV60585450; called by muse, mutect2, varscan2
- OR4K2 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 48/390 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV53848357; called by muse, varscan2
- OR51B2 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.33); catalogued as rs898308471, COSV60916201; called by muse, mutect2, varscan2
- OR5AC2 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562786394, COSV100684561, COSV62279251; called by muse, mutect2, varscan2
- OR5AS1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57982912; called by muse, mutect2, varscan2
- OR5H2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100788696, COSV62351571; called by muse, mutect2, varscan2
- OR5K1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60303518; called by muse, mutect2, varscan2
- OR6N1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV58650385; called by muse, mutect2, varscan2
- OR6N2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs1211755840, COSV104411282, COSV59412829; called by muse, mutect2, varscan2
- OTUD4 | c.1999C>T p.P667S (on ENST00000447906 / NM_001366057.1; = p.P602S on NM_001102653.1) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71382307; called by muse, mutect2, varscan2
- PARP15 | c.1634A>T p.D545V (on ENST00000464300 / NM_001113523.3; = p.D311V on NM_152615.2) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59974982; called by mutect2, varscan2
- PAXIP1 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.511); catalogued as COSV68187743; called by muse, mutect2
- PCDH1 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.123); catalogued as COSV54619165; called by muse, mutect2, varscan2
- PCDHA1 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV65376855; called by muse, mutect2, varscan2
- PCDHB8 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.098); catalogued as COSV50813743; called by muse, mutect2, varscan2
- PCDHGC3 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52767362; called by muse, mutect2, varscan2
- PCNX2 | c.3250C>T p.P1084S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50858091; called by muse, mutect2, varscan2
- PCTP | c.446T>G p.V149G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52123808; called by muse, mutect2
- PDCD11 | c.3095C>T p.T1032I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV63935293; called by muse, mutect2, varscan2
- PDGFC | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV56854743; called by muse, mutect2, varscan2
- PDPN | c.261A>T p.E87D (on ENST00000621990; = p.E163D on NM_006474.4) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.819); catalogued as COSV53850912; called by muse, mutect2, varscan2
- PDZD2 | c.8311G>A p.V2771M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.11); catalogued as COSV56872129; called by muse, mutect2, varscan2
- PDZD4 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.152); catalogued as rs1557076134, COSV51251393; called by muse, mutect2, varscan2
- PEG3 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs751288968, COSV55634973, COSV99688124; called by muse, mutect2, varscan2
- PHYKPL | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs775663443, COSV57426229; called by mutect2, varscan2
- PIGK | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV63063562; called by muse, mutect2, varscan2
- PIH1D2 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as rs782224372, COSV99735527; called by muse, mutect2, varscan2
- PIK3C2G | c.3380G>A p.G1127E (on ENST00000676171; = p.G1086E on NM_004570.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as COSV56809402, COSV56832734; called by muse, varscan2
- PLBD1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV53696247; called by muse, mutect2
- PLG | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as COSV51986338; called by muse, mutect2, varscan2
- PMEL | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV59388630; called by muse, mutect2, varscan2
- PNPLA5 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53376286; called by muse, mutect2, varscan2
- POF1B | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53139926, COSV53141762; called by muse, mutect2, varscan2
- PPARG | c.1114G>A p.G372S (on ENST00000287820 / NM_015869.5; = p.G342S on NM_005037.7) | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs1273044250, COSV55145015; called by muse, mutect2, varscan2
- PPP6C | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs865855853, COSV65207519; called by muse, mutect2, varscan2
- PPRC1 | c.2704C>T p.L902F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.426); catalogued as rs1286477093, COSV53388471; called by muse, mutect2, varscan2
- PREX2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201372935, COSV99906079; called by muse, varscan2
- PRICKLE2 | c.1537A>G p.M513V (on ENST00000295902; = p.M457V on NM_198859.4) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV55771493; called by muse, mutect2, varscan2
- PRKAG3 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.134); catalogued as COSV52103716, COSV52103936; called by muse, mutect2, varscan2
- PRLR | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.37); catalogued as rs866841150, COSV51493740; called by muse, mutect2, varscan2
- PROKR2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1042038054, COSV54085035; called by muse, mutect2, varscan2
- PRR30 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV53205255; called by mutect2, varscan2
- PRSS45P | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV70577983; called by muse, mutect2, varscan2
- PUS1 | c.892G>T p.V298F | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59036537; called by muse, mutect2, varscan2
- RAD54L2 | c.3571T>A p.S1191T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV56581488; called by muse, mutect2
- RBBP6 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV60508351; called by muse, mutect2, varscan2
- RET | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV60708143, COSV60708846; called by muse, mutect2, varscan2
- RHOXF2B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV65054868; called by muse, mutect2, varscan2
- RIC3 | c.323T>A p.F108Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV58304779; called by muse, mutect2, varscan2
- RIMS1 | c.3626G>A p.G1209E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV53457285, COSV53461441; called by muse, mutect2, varscan2
- RLBP1 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51529340; called by muse, mutect2, varscan2
- RLF | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV65653141; called by muse, mutect2
- RLIM | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1304657960, COSV60327800; called by muse, mutect2, varscan2
- RNF213 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1215728747, COSV60622321; called by muse, mutect2, varscan2
- RNF25 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1251689161, COSV55309606; called by muse, mutect2, varscan2
- ROBO2 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV59936994; called by muse, mutect2, varscan2
- RP1 | c.3352C>T p.H1118Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55111043; called by muse, mutect2, varscan2
- RP1 | c.3709G>A p.G1237R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.823); catalogued as COSV55126130, COSV99609454; called by muse, mutect2, varscan2
- RP1L1 | c.3283G>A p.G1095S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV66760009; called by muse, mutect2, varscan2
- RPTN | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV60168823, COSV60169116; called by muse, mutect2, varscan2
- RSAD1 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1010567613, COSV51956743, COSV51957458; called by muse, mutect2, varscan2
- RSF1 | c.1364T>A p.F455Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.043); catalogued as COSV57842289; called by muse, mutect2, varscan2
- RSPH14 | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.089); catalogued as COSV53271990; called by muse, mutect2, varscan2
- RUSC2 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100770943; called by muse, mutect2
- RXFP4 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58142534; called by muse, mutect2, varscan2
- RYR1 | c.7583C>T p.P2528L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62110196; called by muse, mutect2, varscan2
- SCAF8 | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65793785; called by muse, mutect2, varscan2
- SCAMP5 | c.402G>A p.W134* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | catalogued as COSV100723844; called by muse, mutect2, varscan2
- SCEL | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62993155, COSV62994539; called by muse, mutect2, varscan2
- SCN11A | c.2231C>T p.S744L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV56578068; called by muse, mutect2, varscan2
- SCN11A | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV56578078; called by muse, mutect2, varscan2
- SCN9A | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV57623257; called by muse, mutect2, varscan2
- SCTR | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs572299359, COSV50033601; called by mutect2, varscan2
- SCTR | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99191666; called by muse, mutect2, varscan2
- SEMA3E | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as COSV57107678; called by muse, mutect2, varscan2
- SERPINE3 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.033); catalogued as rs1349106919, COSV60880515; called by muse, mutect2, varscan2
- SGPP2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs777269779, COSV58331714; called by muse, mutect2
- SH2B1 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59466735; called by muse, mutect2
- SH3RF1 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52925155; called by muse, mutect2, varscan2
- SHANK2 | c.2522G>T p.R841L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV53593280, COSV53617988; called by muse, mutect2
- SIPA1L1 | c.4940C>T p.S1647L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1382456163, COSV62173449; called by muse, varscan2
- SLC12A6 | c.1469G>A p.G490E (on ENST00000354181 / NM_001365088.1; = p.G439E on NM_005135.2) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51631535; called by muse, mutect2
- SLC15A4 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV57163759; called by muse, mutect2, varscan2
- SLC22A6 | c.1115T>G p.V372G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV64561034; called by muse, mutect2, varscan2
- SLC4A8 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60650252; called by muse, mutect2, varscan2
- SLC7A9 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV50083407, COSV50093616; called by muse, mutect2, varscan2
- SLIT2 | c.4513G>A p.E1505K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.056); catalogued as rs779153208, COSV56585349; called by muse, mutect2, varscan2
- SLITRK3 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.36); catalogued as COSV53853221; called by muse, mutect2, varscan2
- SLITRK4 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV62026037; called by muse, mutect2, varscan2
- SLITRK4 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567436; called by muse, mutect2, varscan2
- SNAP47 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59920030; called by muse, mutect2, varscan2
- SNRK | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs889935483, COSV56066227; called by muse, mutect2, varscan2
- SNX29 | c.304T>C p.F102L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV101625453; called by mutect2, varscan2
- SPHKAP | c.2699A>G p.N900S | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV60893415; called by muse, mutect2, varscan2
- SPNS1 | c.749C>G p.S250* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV57956691; called by muse, varscan2
- SPTA1 | c.6781C>T p.Q2261* | Nonsense Mutation (SNP) | VAF 35/187 reads (19%) | catalogued as COSV63758972; called by muse, mutect2, varscan2
- ST14 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763171074, COSV53836851; called by muse, mutect2, varscan2
- ST18 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV52508636; called by muse, mutect2, varscan2
- ST6GAL2 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 31/86 reads (36%) | PolyPhen probably damaging (0.979); catalogued as COSV62418082; called by muse, mutect2, varscan2
- STK19 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV61715039; called by muse, mutect2, varscan2
- SULF2 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV63419879; called by muse, mutect2, varscan2
- SUSD2 | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100844284, COSV64205340; called by muse, mutect2, varscan2
- SYNE1 | c.11138C>T p.S3713F (on ENST00000367255 / NM_182961.4; = p.S3698F on NM_033071.3) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV55096355, COSV55115259; called by muse, mutect2, varscan2
- SYNE1 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55030610; called by muse, mutect2, varscan2
- TAF1L | c.1678C>T p.L560F | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs1407746743, COSV54262866; called by muse, mutect2, varscan2
- TBC1D9 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71308852; called by muse, mutect2
- TBX21 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as COSV51597937; called by muse, mutect2
- TCF20 | c.5527C>T p.P1843S | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1288954312, COSV59495777; called by muse, mutect2, varscan2
- TENM1 | c.3730G>A p.D1244N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV64442301; called by muse, mutect2, varscan2
- THEG | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765469573, COSV61074893; called by muse, varscan2
- THSD7A | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV69856108, COSV69856171; called by muse, mutect2
- THSD7B | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as COSV55657721; called by muse, mutect2, varscan2
- TLN2 | c.3521C>T p.A1174V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV60895502; called by muse, mutect2
- TMEM225 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1044564126, COSV66692961; called by muse, mutect2, varscan2
- TMPRSS11B | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV60291306, COSV60294027; called by muse, mutect2, varscan2
- TNRC6C | c.2719C>T p.Q907* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV56952595; called by muse, mutect2, varscan2
- TRAV34 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs1430606901; called by muse, mutect2, varscan2
- TRHR | c.837G>A p.W279* | Nonsense Mutation (SNP) | VAF 65/218 reads (30%) | catalogued as rs143656279, COSV61236379; called by muse, mutect2, varscan2
- TRHR | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV61236389; called by muse, varscan2
- TRIM58 | c.498A>C p.K166N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV63572175; called by muse, mutect2, varscan2
- TRPV5 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54689587; called by muse, varscan2
- TSC22D2 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.063); catalogued as COSV100721248; called by muse, mutect2, varscan2
- TSC22D2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV100721249; called by muse, mutect2, varscan2
- TSPAN33 | c.105G>A p.V35= | Splice Region (SNP) | VAF 17/114 reads (15%) | catalogued as COSV56827866; called by muse, mutect2, varscan2
- TTLL3 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100047706; called by muse, mutect2
- TTN | c.5294G>A p.G1765D (on ENST00000591111; = p.G1719D on NM_003319.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | PolyPhen benign (0.001); catalogued as COSV60334273; called by muse, mutect2, varscan2
- TUBA3C | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as rs774052893, COSV68027856; called by muse, mutect2, varscan2
- TUT1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV53471953; called by muse, mutect2, varscan2
- UGT2A2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.231); catalogued as COSV54138004; called by muse, mutect2, varscan2
- UGT2B15 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV57732977; called by muse, mutect2, varscan2
- UGT2B4 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs774803544, COSV59317964, COSV59318763; called by muse, mutect2, varscan2
- UGT2B4 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1207803837, COSV59318186; called by mutect2, varscan2
- UNC13D | c.825G>T p.Q275H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52887286; called by muse, mutect2, varscan2
- USP26 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs779941047, COSV63709262; called by mutect2, varscan2
- USP34 | c.5983C>T p.P1995S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV68406288; called by muse, mutect2, varscan2
- VN1R4 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV100237584, COSV60805600; called by muse, mutect2, varscan2
- VPS13C | c.6860T>C p.L2287S (on ENST00000644861 / NM_020821.3; = p.L2244S on NM_017684.5) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51423425; called by muse, mutect2, varscan2
- WDR31 | c.181C>T p.H61Y (on ENST00000374193 / NM_001006615.3; = p.H60Y on NM_145241.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1192598901, COSV59147834; called by muse, mutect2
- WDR44 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99561758; called by muse, varscan2
- WIPF1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); catalogued as COSV55820256; called by muse, mutect2, varscan2
- XDH | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV65151108; called by muse, mutect2, varscan2
- XIRP2 | c.9968C>T p.T3323I (on ENST00000628543; = p.T3498I on NM_152381.6) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54732819; called by muse, mutect2, varscan2
- YBX1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs753899176, COSV58440165; called by muse, mutect2, varscan2
- YY1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as COSV51764358; called by muse, mutect2, varscan2
- YY1AP1 | c.1412C>T p.P471L (on ENST00000295566 / NM_139118.2; = p.P414L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55124719; called by muse, mutect2, varscan2
- ZBTB4 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs762795732, COSV60142295; called by muse, varscan2
- ZC3H6 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781180324, COSV59670520; called by muse, mutect2, varscan2
- ZFP42 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs866099446, COSV58817784; called by muse, mutect2, varscan2
- ZFR | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.984); catalogued as rs1221619921, COSV54057627; called by muse, mutect2, varscan2
- ZIM3 | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1476598898, COSV54146498; called by muse, mutect2, varscan2
- ZNF185 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV59278109; called by muse, mutect2, varscan2
- ZNF254 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61644745; called by mutect2, varscan2
- ZNF285 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs765204241, COSV58409743; called by muse, mutect2, varscan2
- ZNF423 | c.1847C>A p.S616Y (on ENST00000563137 / NM_001379286.1; = p.S608Y on NM_015069.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as COSV52203865; called by muse, mutect2, varscan2
- ZNF45 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867113088, COSV54194692; called by muse, mutect2, varscan2
- ZNF461 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV64455248; called by muse, mutect2, varscan2
- ZNF594 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.118); catalogued as COSV68386195; called by muse, mutect2, varscan2
- ZNF677 | c.1567G>C p.A523P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100447797, COSV100447947, COSV61721480; called by muse, mutect2, varscan2
- ZNF780B | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55467399; called by mutect2, varscan2
- ZNF813 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV101124940; called by muse, mutect2, varscan2
- AFF4 | c.2278del p.V760Ffs*82 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- ARID2 | c.5042C>T p.S1681F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASAH2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH9 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- GPR179 | c.4774G>A p.E1592K (on ENST00000621958; = p.E1591K on NM_001004334.4) | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.653); called by muse, varscan2
- HOXB8 | c.456dup p.Y153Lfs*16 | Frame Shift Ins (INS) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- KXD1 | c.301+2dup p.X101_splice | Splice Site (INS) | VAF 4/17 reads (24%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PLAAT5 | c.241_248del p.L81Gfs*13 | Frame Shift Del (DEL) | VAF 43/239 reads (18%) | called by mutect2, pindel, varscan2
- PTPN20 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AADACL4 | c.312G>A p.P104= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs776635004, COSV66106732; called by muse, mutect2, varscan2
- ABCA13 | c.11790C>T p.L3930= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV71288409; called by muse, mutect2, varscan2
- ABCC12 | c.576C>T p.I192= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100252970; called by muse, mutect2, varscan2
- ACKR2 | c.660C>T p.L220= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV56177815; called by muse, mutect2, varscan2
- ACTRT1 | c.990C>T p.I330= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV64419044; called by muse, varscan2
- ADAM29 | c.1488G>A p.K496= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV63666888, COSV63667955; called by muse, mutect2, varscan2
- AGXT2 | c.537G>A p.L179= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as COSV51490610; called by muse, mutect2, varscan2
- AKAP12 | c.1422G>A p.E474= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV53581848; called by muse, mutect2, varscan2
- AKR1B1 | c.369C>T p.F123= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV53646451; called by muse, mutect2, varscan2
- AL121899.2 | c.1431G>A p.G477= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs962271357, COSV67350014; called by muse, mutect2, varscan2
- ALOX12B | c.345G>A p.E115= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV59876081; called by muse, mutect2, varscan2
- AMIGO2 | c.1506G>A p.G502= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV56976085; called by muse, mutect2
- ANK3 | c.1749C>T p.L583= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV55080318; called by muse, mutect2, varscan2
- APBA1 | c.1938C>T p.I646= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV55237190; called by muse, mutect2, varscan2
- APOB | c.2775C>T p.I925= | Silent (SNP) | VAF 57/255 reads (22%) | catalogued as COSV51951445; called by muse, mutect2, varscan2
- ART3 | c.252C>T p.I84= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV61915912; called by muse, mutect2, varscan2
- ATP12A | c.2391G>A p.K797= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as rs747429794, COSV54523018; called by muse, mutect2, varscan2
- ATP7B | c.2442C>T p.I814= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV54443857, COSV99666349; called by muse, mutect2, varscan2
- ATP7B | c.2037C>T p.H679= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV54442646, COSV54443866; called by muse, mutect2, varscan2
- BMP5 | c.132G>A p.R44= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100895867, COSV63706405; called by muse, mutect2, varscan2
- C1orf74 | c.678T>C p.S226= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV50559991; called by muse, mutect2, varscan2
- CASP10 | c.1308C>T p.F436= (on ENST00000272879 / NM_032974.5; = p.F393= on NM_001230.5) | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs767576810, COSV53780460; called by muse, mutect2, varscan2
- CEACAM5 | c.1227G>A p.L409= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV55754979; called by muse, mutect2, varscan2
- CEP250 | c.5712G>A p.L1904= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV61174174; called by muse, mutect2, varscan2
- CLCN5 | c.1767G>A p.R589= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100260299; called by muse, mutect2, varscan2
- CNTNAP3 | c.2418C>T p.F806= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs772923010, COSV99904095; called by muse, mutect2, varscan2
- CNTNAP3 | c.2289G>A p.Q763= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV52663568; called by muse, mutect2
- CNTNAP5 | c.708G>A p.G236= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV70510936; called by muse, mutect2, varscan2
- COTL1 | c.363G>A p.E121= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV52291434; called by muse, mutect2, varscan2
- CRB1 | c.1707C>T p.F569= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs201885772, COSV66329457; called by muse, mutect2, varscan2
- CRNN | c.651G>A p.Q217= | Silent (SNP) | VAF 69/238 reads (29%) | catalogued as rs1364395299, COSV55123788; called by muse, mutect2, varscan2
- CTNND2 | c.1398C>T p.S466= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1316786685, COSV58913714; called by muse, mutect2, varscan2
- CYP2C18 | c.391C>T p.L131= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53675062; called by muse, mutect2, varscan2
- CYTH3 | c.813C>T p.L271= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV63441206; called by muse, mutect2
- DCST2 | c.957C>T p.V319= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV55054488; called by muse, mutect2
- DCTN1 | c.679C>T p.L227= | Silent (SNP) | VAF 43/241 reads (18%) | catalogued as COSV100721004; called by muse, mutect2, varscan2
- DCTN1 | c.678C>T p.D226= | Silent (SNP) | VAF 43/236 reads (18%) | catalogued as COSV100721005; called by muse, mutect2, varscan2
- DEAF1 | c.1284C>T p.V428= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV58609236; called by muse, mutect2, varscan2
- DNAH17 | c.3351G>A p.G1117= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs762586933, COSV67760858; called by muse, mutect2, varscan2
- DNAH17 | c.327G>A p.L109= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV67760860; called by muse, mutect2, varscan2
- DNAH2 | c.7626C>T p.S2542= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV66726853; called by muse, mutect2, varscan2
- DNMT3B | c.63C>T p.I21= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV52423106; called by muse, mutect2, varscan2
- DOCK10 | c.993C>T p.N331= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV51427280; called by muse, mutect2, varscan2
- DOCK10 | c.423A>G p.E141= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV51427297; called by muse, mutect2, varscan2
- DPP10 | c.318G>A p.L106= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV59724786; called by muse, mutect2, varscan2
- DRC7 | c.1902C>T p.F634= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV61057717; called by mutect2, varscan2
- DSG1 | c.885G>A p.L295= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1239241533, COSV57139176; called by muse, mutect2, varscan2
- DSP | c.1695C>T p.I565= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs752714010, COSV65795774; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- EEF2 | c.1461C>T p.T487= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs780521912, COSV58580926; called by muse, mutect2, varscan2
- EPO | c.252G>A p.G84= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs759640016, COSV53162121; called by muse, mutect2, varscan2
- FAM71B | c.1302G>A p.K434= | Silent (SNP) | VAF 37/375 reads (10%) | catalogued as rs375898947, COSV100262152; called by muse, mutect2, varscan2
- FAT3 | c.1647C>G p.A549= | Silent (SNP) | VAF 95/420 reads (23%) | catalogued as COSV53171175; called by muse, mutect2, varscan2
- FZD10 | c.1191C>T p.F397= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs777162340, COSV57475656; called by muse, mutect2, varscan2
- GABRA1 | c.231C>T p.F77= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as rs566224462, COSV50101608; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRE | c.1044C>T p.F348= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs780864713, COSV64821270; called by muse, mutect2, varscan2
- GAL3ST3 | c.600C>T p.F200= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1409974202, COSV61748977; called by muse, mutect2, varscan2
- GBP7 | c.1242A>G p.S414= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as rs1211729958, COSV54011887; called by muse, mutect2, varscan2
- GFPT2 | c.1047C>T p.T349= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV53812345; called by muse, mutect2, varscan2
- GNAZ | c.279C>T p.I93= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as rs755459742, COSV50741590; called by muse, mutect2, varscan2
- GPR158 | c.2691G>A p.S897= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs376737455; called by muse, mutect2, varscan2
- GPR50 | c.117C>T p.I39= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs1170471807, COSV54440737; called by muse, mutect2, varscan2
- GPR78 | c.795C>T p.L265= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs779541119, COSV66763068; called by muse, mutect2, varscan2
- GPX6 | c.15C>T p.F5= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV62659007; called by muse, mutect2
- HCN4 | c.1056G>A p.V352= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99983987; called by muse, mutect2, varscan2
- HERC1 | c.11818C>T p.L3940= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV71250137; called by muse, mutect2, varscan2
- HOXD3 | c.843C>T p.A281= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV50885350; called by muse, mutect2, varscan2
- IGDCC3 | c.588C>T p.I196= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV60080168; called by muse, mutect2, varscan2
- IGF2BP2 | c.1299C>T p.F433= | Silent (SNP) | VAF 35/230 reads (15%) | catalogued as COSV60491084; called by muse, mutect2, varscan2
- IGHG3 | c.786C>T p.I262= | Silent (SNP) | VAF 49/248 reads (20%) | catalogued as rs375368765; called by muse, mutect2, varscan2
- IGHG4 | c.192C>T p.S64= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- IL17A | c.129G>A p.R43= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as rs1244676765, COSV100391586; called by muse, mutect2, varscan2
- IL22RA1 | c.219G>A p.R73= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV54630371, COSV99582863; called by muse, mutect2, varscan2
- IMPG1 | c.222C>T p.F74= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs780783100, COSV64053839; called by muse, mutect2
- ITGB8 | c.828T>C p.A276= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99751920; called by muse, mutect2, varscan2
- ITIH5 | c.405G>A p.E135= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs749252937, COSV56914239, COSV56917741; called by muse, mutect2, varscan2
- IZUMO1R | c.498C>T p.L166= (on ENST00000440961; = p.L173= on NM_001199206.3) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60623517; called by muse, mutect2, varscan2
- JAKMIP3 | c.2157G>A p.K719= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV53829042; called by muse, mutect2
- KCNK1 | c.615C>A p.V205= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV64036431; called by muse, varscan2
- KCNK5 | c.792G>A p.K264= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV63989380; called by muse, varscan2
- KIF3C | c.1953C>T p.F651= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs1434741051, COSV53101741; called by muse, mutect2, varscan2
- KIR2DL1 | c.387T>C p.P129= | Silent (SNP) | VAF 61/169 reads (36%) | catalogued as COSV52415284; called by muse, mutect2, varscan2
- KLHL13 | c.699G>A p.L233= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV53246468, COSV53252667; called by muse, mutect2, varscan2
- KLKB1 | c.390G>A p.K130= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV52999234; called by muse, mutect2, varscan2
- KMT2D | c.2235C>T p.P745= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV56484690; called by muse, mutect2, varscan2
- KRT6A | c.642C>T p.F214= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs767532911, COSV58107766; called by muse, mutect2, varscan2
- KRT82 | c.234C>T p.F78= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs142775418; called by muse, mutect2
- L1CAM | c.456G>A p.E152= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV62830091; called by muse, mutect2, varscan2
- LAMB3 | c.810C>T p.S270= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV61919593; called by muse, mutect2, varscan2
- LILRA2 | c.831G>A p.Q277= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV52187878; called by muse, mutect2, varscan2
- LMX1A | c.423G>A p.Q141= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs866613599, COSV54227775; called by muse, mutect2, varscan2
- LPP | c.1659C>T p.V553= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100447861; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.327C>T p.I109= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV58187664; called by muse, mutect2, varscan2
- MAGI2 | c.516C>T p.L172= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs763377103, COSV62697170; called by mutect2, varscan2
- MB21D2 | c.267C>T p.L89= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV66665918; called by muse, mutect2, varscan2
- MCM3AP | c.2256C>T p.T752= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV52445404; called by muse, mutect2, varscan2
- MLF2 | c.720C>T p.S240= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs754329435, COSV99180106; called by muse, mutect2, varscan2
- MUC16 | c.38583C>T p.F12861= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as rs374854853; called by muse, mutect2, varscan2
- MYH4 | c.5085C>T p.S1695= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV55125809; called by muse, mutect2, varscan2
- MYH4 | c.4464G>A p.V1488= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV55125817; called by muse, mutect2, varscan2
- NIN | c.609C>T p.N203= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs773293893, COSV55405531; called by muse, mutect2, varscan2
- NLRP7 | c.2049A>G p.K683= (on ENST00000340844 / NM_206828.3; = p.K655= on NM_139176.3) | Silent (SNP) | VAF 65/185 reads (35%) | catalogued as COSV60181640; called by muse, mutect2, varscan2
- NOC2L | c.786C>T p.S262= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1365699872, COSV58987833, COSV58990866; called by muse, mutect2, varscan2
- NOL9 | c.846T>C p.L282= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs1166494500, COSV66626937; called by muse, mutect2, varscan2
- NOTCH3 | c.5676C>T p.I1892= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs938255360, COSV54649235; called by muse, mutect2, varscan2
- NOTCH4 | c.3000G>A p.G1000= | Silent (SNP) | VAF 78/256 reads (30%) | catalogued as rs976109058, COSV66683681; called by muse, mutect2, varscan2
- NPAP1 | c.441G>A p.E147= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV61506110; called by muse, mutect2, varscan2
- OR10P1 | c.645T>C p.I215= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100548196; called by muse, mutect2, varscan2
- OR14I1 | c.357C>T p.D119= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs367802071, COSV61198868; called by muse, mutect2, varscan2
- OR1C1 | c.705G>A p.Q235= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV68716349, COSV68716584; called by muse, mutect2, varscan2
- OR1F1 | c.309C>T p.F103= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs267604532, COSV58960923; called by muse, mutect2, varscan2
- OR2A12 | c.114G>A p.L38= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV68821369, COSV68821980; called by muse, mutect2, varscan2
- OR2AK2 | c.618C>T p.I206= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV63560562; called by muse, mutect2, varscan2
- OR2L13 | c.90C>A p.I30= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV63548815, COSV63560565; called by muse, mutect2, varscan2
- OR2W3 | c.99C>T p.I33= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs372830127, COSV100831577; called by muse, mutect2, varscan2
- OR4D1 | c.273G>A p.T91= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs17222013, COSV52124886; called by muse, mutect2, varscan2
- OR51A2 | c.661C>T p.L221= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV66748756; called by muse, mutect2, varscan2
- OR51F2 | c.696C>T p.S232= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV59066027; called by muse, mutect2, varscan2
- OR52M1 | c.933G>A p.R311= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs760005264, COSV64172465; called by muse, mutect2, varscan2
- OR5AK2 | c.702G>A p.R234= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs780254019, COSV58803826; called by muse, mutect2, varscan2
- OR5D14 | c.192C>T p.F64= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs1456845522, COSV59455426; called by mutect2, varscan2
- OR5L2 | c.186C>T p.F62= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as COSV65723514; called by muse, mutect2, varscan2
- OR5W2 | c.891G>A p.V297= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs757159044, COSV60618280; called by muse, mutect2
- OR6T1 | c.207G>A p.L69= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100190099; called by muse, mutect2
- PANX3 | c.996C>T p.F332= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV52512859; called by muse, mutect2, varscan2
- PAPPA | c.4011C>T p.F1337= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs752953056, COSV60290966; called by muse, mutect2, varscan2
- PCDHB5 | c.1137G>A p.R379= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV50648522, COSV50669555; called by muse, mutect2, varscan2
- PCED1B | c.51C>T p.F17= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV71395230; called by muse, mutect2, varscan2
- PCLO | c.10824C>T p.S3608= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV61664410; called by muse, mutect2, varscan2
- PCNX2 | c.3495G>A p.E1165= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV50883525; called by muse, mutect2, varscan2
- PDE4D | c.573C>T p.F191= (on ENST00000340635 / NM_001104631.2; = p.F55= on NM_006203.4) | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1445888956, COSV58978534; called by muse, mutect2, varscan2
- PDE4DIP | c.3315C>T p.L1105= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs782009765, COSV57727098; called by mutect2, varscan2
- PDE6B | c.639G>A p.L213= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV55330730; called by muse, mutect2
- PDZRN4 | c.2835G>A p.E945= (on ENST00000402685 / NM_001164595.2; = p.E687= on NM_013377.4) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs757164729, COSV54216533; called by muse, mutect2, varscan2
- PEMT | c.195C>T p.F65= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV55131484; called by muse, mutect2, varscan2
- PLEKHF1 | c.201C>T p.I67= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV101460745, COSV71410383; called by muse, mutect2, varscan2
- PRAMEF19 | c.876G>A p.K292= | Silent (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- PRKD2 | c.1959C>T p.F653= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV52189571; called by muse, mutect2
- PRPF4 | c.726C>T p.S242= (on ENST00000374198 / NM_001322267.2; = p.S243= on NM_004697.5) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV65253437; called by muse, mutect2, varscan2
- PSG5 | c.624G>A p.T208= | Silent (SNP) | VAF 30/227 reads (13%) | catalogued as rs779008783, COSV61653986; called by muse, varscan2
- PSG7 | c.1209G>A p.K403= | Silent (SNP) | VAF 58/104 reads (56%) | catalogued as COSV68446564; called by muse, mutect2, varscan2
- RAD54L2 | c.3573C>T p.S1191= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- RANBP2 | c.2923T>C p.L975= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV51708412; called by muse, mutect2, varscan2
- RGS6 | c.363G>A p.S121= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs200956325, COSV59577491; called by muse, mutect2, varscan2
- SCG2 | c.1554C>T p.I518= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV59540233, COSV59540405; called by muse, mutect2, varscan2
- SCN8A | c.501G>A p.G167= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100634048; called by muse, mutect2
- SDR42E1 | c.462G>A p.R154= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV61095074; called by muse, mutect2
- SFMBT2 | c.1845C>T p.I615= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs773641504, COSV62812212; called by muse, mutect2, varscan2
- SGSM1 | c.2502G>A p.Q834= (on ENST00000400359 / NM_001039948.4; = p.Q773= on NM_133454.3) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63082736; called by muse, varscan2
- SH2B1 | c.1803C>T p.L601= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs527954657, COSV59461182, COSV59466750; called by muse, mutect2
- SLC22A10 | c.276C>T p.V92= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV60423440; called by muse, mutect2, varscan2
- SLC22A12 | c.231C>T p.I77= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV60573962; called by muse, mutect2, varscan2
- SLC2A14 | c.741G>A p.T247= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs756918734, COSV61585491; called by muse, mutect2, varscan2
- SLC38A1 | c.444C>T p.F148= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs371916780; called by muse, mutect2, varscan2
- SLC4A10 | c.1635C>T p.L545= (on ENST00000446997 / NM_001354461.2; = p.L515= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV55798749; called by muse, mutect2, varscan2
- SMS | c.771C>T p.I257= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs751939607, COSV65115237; called by muse, mutect2, varscan2
- SMS | c.1035C>T p.I345= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs749489883, COSV65115251; called by muse, mutect2, varscan2
- SPAG11B | c.264G>A p.V88= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1296635899, COSV99873149; called by muse, varscan2
- SPIDR | c.2172C>T p.D724= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs938956525, COSV52390240; called by muse, mutect2, varscan2
- STARD13 | c.2076C>T p.L692= (on ENST00000336934 / NM_001243476.3; = p.L574= on NM_052851.3) | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs373241738, COSV55232274; called by muse, mutect2, varscan2
- STARD7 | c.943C>T p.L315= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1364314061, COSV61526699; called by muse, varscan2
- STOML3 | c.636G>A p.R212= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV65511884; called by muse, mutect2, varscan2
- SYT17 | c.1266C>T p.I422= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs765529724, COSV62546217; called by muse, mutect2, varscan2
- TAF1L | c.1962A>G p.S654= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs771101955, COSV54268804; called by muse, mutect2, varscan2
- TAS2R38 | c.198C>T p.F66= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV101516478, COSV71885666; called by muse, mutect2, varscan2
- TAS2R42 | c.375G>A p.R125= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV62084927; called by muse, mutect2, varscan2
- TAS2R60 | c.390C>T p.F130= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as rs774950147, COSV60332053; called by muse, mutect2, varscan2
- TBC1D2 | c.1341C>T p.F447= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs766557404, COSV59788737; called by muse, mutect2, varscan2
- THSD7B | c.4719C>T p.F1573= (on ENST00000272643; = p.F1571= on NM_001316349.2) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV55658162; called by muse, mutect2, varscan2
- TLE3 | c.1272C>T p.D424= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as COSV58168318; called by muse, mutect2, varscan2
- TMEM63C | c.672C>T p.I224= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1176316094, COSV53608635; called by muse, mutect2, varscan2
- TNXB | c.5934G>A p.L1978= (on ENST00000647633; = p.L1731= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as COSV64488405; called by muse, mutect2, varscan2
- TRAV12-3 | c.165C>T p.F55= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs1158023491; called by muse, mutect2, varscan2
- TRIB1 | c.369C>T p.P123= | Silent (SNP) | VAF 53/339 reads (16%) | catalogued as rs757419962, COSV61335585; called by muse, mutect2, varscan2
- TRPS1 | c.2646C>T p.S882= (on ENST00000220888 / NM_001330599.2; = p.S895= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV55261239; called by muse, mutect2, varscan2
- TSHB | c.111T>C p.A37= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV56655571; called by muse, mutect2, varscan2
- TSPYL6 | c.723G>A p.R241= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV57820030; called by muse, mutect2, varscan2
- TTLL3 | c.1293C>T p.S431= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100047710; called by muse, mutect2, varscan2
- TUBAL3 | c.339C>T p.G113= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV66814719; called by muse, mutect2, varscan2
- UGT2B15 | c.1461C>T p.I487= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV57736524; called by muse, mutect2, varscan2
- UQCRC1 | c.936C>T p.G312= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52553026; called by muse, mutect2, varscan2
- USP26 | c.2361C>T p.S787= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV63709718; called by muse, varscan2
- VIPR1 | c.756G>A p.R252= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs267599824, COSV100285699, COSV57297269; called by muse, mutect2, varscan2
- VPS35 | c.315C>T p.I105= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV54481133; called by mutect2, varscan2
- WDR44 | c.753T>A p.S251= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as COSV99561759; called by muse, varscan2
- XIRP1 | c.2922C>T p.P974= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV61140960; called by muse, mutect2, varscan2
- XKR3 | c.951C>T p.I317= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV58887892; called by muse, mutect2, varscan2
- ZFP57 | c.456C>T p.P152= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV65306968; called by muse, mutect2, varscan2
- ZFYVE9 | c.528C>T p.S176= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- ZNF142 | c.2913C>T p.S971= (on ENST00000411696 / NM_001379660.1; = p.S771= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV68743342; called by muse, varscan2
- ZNF236 | c.2502G>A p.G834= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs1353591670, COSV53497315; called by muse, mutect2, varscan2
- ZNF334 | c.996G>A p.R332= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV61620059; called by muse, mutect2, varscan2
- ZNF431 | c.738C>T p.T246= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV60675327; called by muse, mutect2, varscan2
- ZNF514 | c.240C>T p.S80= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV54635327; called by muse, mutect2, varscan2
- ZNF567 | c.939A>G p.E313= (on ENST00000536254 / NM_001322913.1; = p.E282= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV62446457; called by muse, mutect2, varscan2
- ZNF609 | c.3364C>A p.R1122= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV58589810; called by muse, mutect2, varscan2
- ZNF676 | c.285C>T p.F95= (on ENST00000650058; = p.F63= on NM_001001411.3) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV68094860; called by muse, mutect2
- ZNF709 | c.630C>T p.T210= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV67195884; called by muse, mutect2, varscan2
- ZW10 | c.1992C>T p.V664= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV52319262; called by muse, varscan2
- FST | c.953-264G>A | Intron (SNP) | VAF 13/127 reads (10%) | catalogued as COSV99887351; called by muse, mutect2, varscan2
- GPR32 | c.-1C>T | 5'UTR (SNP) | VAF 11/24 reads (46%) | catalogued as rs762705068, COSV99567269; called by muse, mutect2, varscan2
- GSG1 | c.481+66G>A | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100189382; called by muse, mutect2, varscan2
- IFT46 | c.46-786T>G | Intron (SNP) | VAF 31/158 reads (20%) | catalogued as COSV50595290; called by muse, mutect2, varscan2
- MCHR2 | c.*1G>A | 3'UTR (SNP) | VAF 17/47 reads (36%) | catalogued as rs1196922098, COSV99912412; called by muse, mutect2
- MIR1244-3 | n.6A>G | RNA (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- MIR519C | n.25G>A | RNA (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- ODAPH | c.*1G>A | 3'UTR (SNP) | VAF 13/91 reads (14%) | catalogued as rs771966707, COSV61141773; called by muse, mutect2, varscan2
- OR2U1P | n.630C>T | RNA (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- OR2W5 | n.624G>A | RNA (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5120807 G>A | 3'Flank (SNP) | VAF 13/53 reads (25%) | catalogued as rs1437180652; called by muse, mutect2, varscan2
- PCBP4 | c.388-12C>T | Intron (SNP) | VAF 16/46 reads (35%) | catalogued as rs923984011, COSV59056091; called by muse, mutect2, varscan2
- PTPN2 | c.161-3844G>A | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100518669; called by muse, mutect2, varscan2
- REPS2 | c.*1433G>A | 3'UTR (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100381430; called by muse, mutect2, varscan2
- RMDN2 | c.453-22020C>T | Intron (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52229513; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302068 G>A | 5'Flank (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23848G>A | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as COSV67449959; called by muse, mutect2
- SNORD115-18 | n.66G>A | RNA (SNP) | VAF 23/125 reads (18%) | catalogued as rs1484826676; called by muse, mutect2, varscan2
- SPATA8 | n.273G>A | RNA (SNP) | VAF 7/56 reads (13%) | catalogued as rs267604397, COSV60703913; called by muse, mutect2
- SUCO | chr1:172532732 G>A | 5'Flank (SNP) | VAF 8/51 reads (16%) | catalogued as COSV55262452, COSV99742333; called by muse, mutect2, varscan2
- SYTL2 | c.1459+3312C>A | Intron (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100314594; called by muse, mutect2, varscan2
- TMEM183B | n.147C>T | RNA (SNP) | VAF 15/71 reads (21%) | catalogued as rs1401269018; called by muse, mutect2, varscan2
- TRPV2 | chr17:16439274 G>A | 3'Flank (SNP) | VAF 14/70 reads (20%) | catalogued as rs768391740; called by muse, mutect2, varscan2
- XIST | n.8626C>T | RNA (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
